Somatic mutation profile of tumor specimen TCGA-44-5643-01A (aliquot TCGA-44-5643-01A-01D-1625-08) from TCGA case TCGA-44-5643, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 53.2 years (19,426 days).
Specimen TCGA-44-5643-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d20c120-22b3-4c99-b5de-5cec0a7dd839.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-5643-10A (Blood Derived Normal), aliquot TCGA-44-5643-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33517eb8-ce28-410f-85b3-e4e14a75e4ad

The open-access MAF lists 142 somatic variants for this specimen: 105 protein-altering or splice-affecting, 36 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 36, Nonsense Mutation 13, Frame Shift Del 4, Splice Site 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH23 | c.8803C>T p.R2935* | Nonsense Mutation (SNP) | VAF 22/118 reads (19%) | catalogued as rs1190307769, CM148915, COSV56495420; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 50/92 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTRT1 | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 62/116 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64420206; called by muse, mutect2, varscan2
- ACTRT3 | c.41C>G p.S14W | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772568987, COSV100377317, COSV57753699; called by mutect2, varscan2
- ADAM11 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776476231, COSV52350043; called by muse, mutect2, varscan2
- ADAM23 | c.607A>G p.R203G | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52233753; called by muse, mutect2, varscan2
- ADAMTS16 | c.2059G>T p.G687* | Nonsense Mutation (SNP) | VAF 25/116 reads (22%) | catalogued as COSV56990019, COSV57010248; called by muse, mutect2, varscan2
- ADGRV1 | c.3464A>C p.Q1155P | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV67997100; called by muse, mutect2, varscan2
- ADRA1B | c.253G>T p.V85F | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV60704834; called by muse, mutect2, varscan2
- AFAP1L2 | c.2330C>T p.S777F (on ENST00000304129 / NM_001351075.1; = p.S773F on NM_032550.3 and 11 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV58417541; called by muse, mutect2, varscan2
- ANKRD30A | c.3115A>G p.R1039G (on ENST00000611781; = p.R983G on NM_052997.2) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV64624002; called by muse, mutect2, varscan2
- ASPM | c.6439C>A p.Q2147K | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV54141341; called by muse, mutect2, varscan2
- BRINP3 | c.2125del p.R709Vfs*2 | Frame Shift Del (DEL) | VAF 20/61 reads (33%) | catalogued as COSV66532839; called by mutect2, pindel, varscan2
- C3AR1 | c.1426G>C p.E476Q | Missense Mutation (SNP) | VAF 156/287 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV99368039, COSV99368386; called by muse, mutect2, varscan2
- CA3 | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53411632; called by muse, mutect2, varscan2
- CDH15 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1162499551, COSV57028477; called by muse, mutect2, varscan2
- CDHR3 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs371586125, COSV100488412; called by muse, mutect2, varscan2
- CHCHD3 | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99365511; called by muse, mutect2, varscan2
- CHD8 | c.3243G>T p.M1081I (on ENST00000646647 / NM_001170629.2; = p.M802I on NM_020920.4) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV67873107; called by muse, mutect2, varscan2
- CPSF1 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as rs1554864545, COSV58236021; called by muse, mutect2, varscan2
- CSMD3 | c.3239C>A p.S1080* (on ENST00000297405 / NM_001363185.1; = p.S976* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV52350418; called by muse, mutect2, varscan2
- CTNNA2 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100559341, COSV58180946; called by muse, mutect2, varscan2
- CUX1 | c.3190A>C p.S1064R | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV52919432; called by muse, mutect2, varscan2
- DNAH5 | c.5013A>T p.E1671D | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.436); catalogued as COSV54258591; called by muse, mutect2, varscan2
- DPP10 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV69790643; called by muse, mutect2, varscan2
- DPYSL4 | c.1118G>A p.G373E | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as COSV58310427; called by muse, mutect2, varscan2
- E2F6 | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56217005; called by muse, mutect2, varscan2
- ENTPD7 | c.1192G>C p.A398P | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.611); catalogued as COSV65113509; called by muse, mutect2, varscan2
- FADD | c.172G>T p.G58W | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100096447; called by muse, mutect2, varscan2
- FAM114A2 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV61078969; called by muse, mutect2, varscan2
- FOXR2 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV59258245; called by muse, mutect2, varscan2
- GAL3ST2 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV51950437; called by muse, mutect2, varscan2
- GFPT2 | c.1630A>T p.M544L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.673); catalogued as COSV53813502; called by muse, mutect2
- GTDC1 | c.385A>T p.N129Y | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54008564; called by muse, mutect2, varscan2
- HCN1 | c.241T>A p.F81I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV57542355; called by muse, mutect2
- HEPH | c.2696C>A p.P899H (on ENST00000343002; = p.P632H on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57974150; called by muse, mutect2, varscan2
- INPP1 | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as COSV59417970; called by muse, mutect2, varscan2
- IRS1 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59341140; called by muse, mutect2, varscan2
- ITSN2 | c.557-1G>A p.X186_splice | Splice Site (SNP) | VAF 45/207 reads (22%) | catalogued as COSV61955016; called by muse, mutect2, varscan2
- KRT7 | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs767599710, COSV59333531; called by muse, mutect2, varscan2
- LEPR | c.3081C>A p.S1027R | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV62753085; called by muse, mutect2, varscan2
- LGR4 | c.2104C>G p.P702A | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.072); catalogued as COSV60821997; called by muse, mutect2, varscan2
- LRP2 | c.10982G>C p.G3661A | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55579520; called by muse, mutect2, varscan2
- LRRC66 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV58637379; called by muse, mutect2, varscan2
- LY75-CD302 | c.5337G>A p.W1779* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV52035252; called by muse, mutect2, varscan2
- LY75-CD302 | c.5134G>C p.E1712Q | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52035265; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3625G>A p.D1209N | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs774208114, COSV51603382; called by muse, mutect2, varscan2
- MARCHF4 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99814011; called by muse, mutect2, varscan2
- MCHR2 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 40/113 reads (35%) | catalogued as rs748678430, COSV56006823; called by muse, mutect2, varscan2
- MGAM | c.1817G>C p.R606T | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72074698, COSV72076154; called by muse, mutect2, varscan2
- MUC16 | c.32827G>T p.A10943S | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.205); catalogued as COSV67468619; called by muse, mutect2, varscan2
- MYOM1 | c.1922C>A p.P641Q | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55287887, COSV55290040; called by muse, mutect2, varscan2
- NAA16 | c.399C>A p.Y133* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV65067311; called by muse, mutect2, varscan2
- NBPF20 | c.16723G>T p.E5575* (on ENST00000369373; = p.E5136* on NM_001278267.1) | Nonsense Mutation (SNP) | VAF 37/183 reads (20%) | catalogued as rs376765079; called by muse, mutect2, varscan2
- NDN | c.271G>C p.A91P | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.137); catalogued as COSV100086195; called by muse, mutect2, varscan2
- NPAS4 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.167); catalogued as COSV60652156, COSV60653292; called by muse, mutect2, varscan2
- NPAS4 | c.1887G>T p.Q629H | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.204); catalogued as COSV60650403; called by muse, mutect2, varscan2
- NRXN3 | c.2834G>A p.S945N (on ENST00000335750 / NM_001330195.2; = p.S572N on NM_004796.6) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV59818648; called by muse, mutect2, varscan2
- OLFM4 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs983870859, COSV54581193; called by muse, mutect2, varscan2
- OR4L1 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs764455064, COSV59849706; called by muse, mutect2
- OR4Q3 | c.501G>A p.M167I | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV59180904; called by muse, mutect2, varscan2
- OR5M10 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs747259529, COSV73242479; called by muse, mutect2, varscan2
- ORC5 | c.1120G>T p.V374F | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99856661; called by muse, mutect2, varscan2
- PCDH11X | c.2594T>C p.I865T | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.346); catalogued as COSV53514066; called by muse, mutect2, varscan2
- PCOLCE | c.190A>T p.I64F | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV53830746; called by muse, varscan2
- PHF19 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as COSV100384249; called by muse, mutect2
- PIK3C2A | c.3682-2A>T p.X1228_splice | Splice Site (SNP) | VAF 10/44 reads (23%) | catalogued as rs779851113, COSV56408068; called by muse, mutect2, varscan2
- PITX1 | c.513C>A p.Y171* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as COSV54763155; called by muse, mutect2, varscan2
- PIWIL3 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.366); catalogued as rs777137117, COSV59998834; called by muse, mutect2, varscan2
- PKHD1 | c.7540G>C p.V2514L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV61898680; called by muse, mutect2, varscan2
- PNPLA6 | c.1309G>A p.D437N (on ENST00000414982 / NM_001166111.2; = p.D389N on NM_006702.5) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as rs760544239, COSV55375052, COSV55386952; called by muse, mutect2, varscan2
- PSG7 | c.795G>C p.K265N | Missense Mutation (SNP) | VAF 68/260 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.777); catalogued as rs764010472, COSV68447038; called by muse, mutect2, varscan2
- PTPN6 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782031352, COSV59686664; called by muse, mutect2, varscan2
- RUBCN | c.210C>G p.I70M | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV99583063; called by muse, mutect2, varscan2
- RUFY1 | c.1293G>A p.M431I | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV60164352; called by muse, mutect2, varscan2
- SALL1 | c.3938G>T p.R1313L | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV51762292, COSV51765734; called by muse, mutect2, varscan2
- SEMA7A | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0.009); catalogued as COSV56092241, COSV56092876; called by muse, mutect2, varscan2
- SI | c.3649G>T p.V1217F | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.958); catalogued as COSV52269028; called by muse, mutect2
- SLC24A3 | c.1513C>A p.L505M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV60113330, COSV60136524; called by muse, mutect2, varscan2
- SLIT1 | c.2236C>T p.R746* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as rs1476967389, COSV56599387; called by muse, mutect2, varscan2
- SLIT2 | c.2815G>T p.D939Y | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV56600027; called by muse, mutect2, varscan2
- SORBS1 | c.3644C>T p.P1215L (on ENST00000361941 / NM_001034954.2; = p.P607L on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53367642; called by muse, mutect2, varscan2
- SOX9 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55421793; called by muse, mutect2, varscan2
- STRA8 | c.841G>C p.E281Q (on ENST00000275764; = p.E259Q on NM_182489.2) | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV51963701; called by muse, mutect2, varscan2
- TAF1L | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.398); catalogued as COSV104386586, COSV54271636; called by muse, mutect2, varscan2
- TAP2 | c.1895A>G p.E632G | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66501510; called by muse, mutect2
- TBXT | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV51617495; called by muse, mutect2, varscan2
- THAP4 | c.1079G>T p.C360F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV67193045; called by muse, mutect2, varscan2
- TOR3A | c.1001C>G p.P334R | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV61681019; called by muse, mutect2, varscan2
- TTLL2 | c.908A>G p.N303S | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1318165270, COSV53446367; called by muse, mutect2, varscan2
- TTN | c.59810C>T p.S19937F (on ENST00000591111; = p.S12513F on NM_003319.4) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | PolyPhen possibly damaging (0.502); catalogued as rs758914564, COSV60417272; called by muse, mutect2, varscan2
- UROC1 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT tolerated (0.19); PolyPhen benign (0.407); catalogued as rs781212470, COSV52031209; called by muse, mutect2, varscan2
- WDR17 | c.2549C>A p.S850* | Nonsense Mutation (SNP) | VAF 21/64 reads (33%) | catalogued as COSV54586424; called by muse, mutect2, varscan2
- WDR43 | c.1204A>G p.K402E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs372117833, COSV56100176; called by muse, mutect2, varscan2
- XYLT1 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.616); catalogued as rs551025574, COSV54487498, COSV99077146; called by muse, mutect2, varscan2
- ZC3H4 | c.410C>G p.S137C | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53418072; called by muse, mutect2, varscan2
- ZFP36L1 | c.483C>G p.F161L | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60547679; called by muse, mutect2, varscan2
- ZIC4 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as rs1353915619, COSV67173829, COSV67174472; called by muse, mutect2, varscan2
- ZMYM5 | c.985A>T p.K329* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as COSV61989224, COSV61990593; called by muse, mutect2, varscan2
- ZNF662 | c.1264C>T p.H422Y | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV60243412; called by muse, mutect2, varscan2
- ZNF804B | c.1127G>T p.S376I | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV100303759, COSV60862576; called by muse, mutect2, varscan2
- ZSCAN9 | c.127A>C p.S43R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99356269; called by muse, mutect2, varscan2
- CDKN2A | c.309_322del p.L104Cfs*11 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- NBEAL1 | c.5714del p.G1905Afs*3 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | called by mutect2, pindel, varscan2
- OR51T1 | c.332del p.L111Cfs*8 | Frame Shift Del (DEL) | VAF 18/98 reads (18%) | called by mutect2, pindel, varscan2
- AC008397.2 | c.1227C>T p.L409= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as rs763893350, COSV53207742; called by muse, mutect2, varscan2
- ALPK1 | c.756C>T p.N252= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs777786049, COSV99452939; called by muse, mutect2, varscan2
- CCDC57 | c.234C>T p.F78= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs748929592, COSV66436370; called by muse, mutect2, varscan2
- CHRM5 | c.876C>A p.A292= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as COSV67248940; called by muse, mutect2, varscan2
- CLMP | c.597C>T p.T199= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV101507441, COSV71650719; called by muse, mutect2, varscan2
- CNTNAP2 | c.1953C>T p.V651= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as rs749504617, COSV62271946; called by muse, mutect2, varscan2
- COL11A1 | c.612G>A p.T204= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs545867472, COSV62197136, COSV62202101; called by muse, mutect2, varscan2
- CPD | c.3969C>T p.C1323= | Silent (SNP) | VAF 40/189 reads (21%) | catalogued as COSV56717103, COSV99852433; called by muse, mutect2, varscan2
- CTNNA2 | c.1236G>A p.K412= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs768539099, COSV58142741; called by muse, mutect2, varscan2
- FHOD3 | c.645C>A p.L215= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs770618045, COSV57189224, COSV57191386; called by muse, mutect2, varscan2
- GALP | c.18C>T p.V6= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV100627841; called by muse, mutect2, varscan2
- HEATR6 | c.2463G>A p.G821= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV51744492, COSV51749775; called by muse, mutect2, varscan2
- HSPA12A | c.606G>A p.T202= | Silent (SNP) | VAF 40/162 reads (25%) | catalogued as rs367814906; called by muse, mutect2, varscan2
- IGKV1-16 | c.333A>G p.Q111= | Silent (SNP) | VAF 38/133 reads (29%) | catalogued as rs1323455593; called by muse, mutect2, varscan2
- IL22RA1 | c.1056C>T p.A352= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV54630778; called by muse, mutect2, varscan2
- ITGA8 | c.1047A>G p.E349= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs1335722994, COSV65237729; called by muse, mutect2, varscan2
- KCNA4 | c.1149C>A p.S383= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV60256683; called by muse, mutect2, varscan2
- KIR3DL1 | c.621A>T p.S207= | Silent (SNP) | VAF 206/386 reads (53%) | catalogued as COSV58497167; called by muse, mutect2, varscan2
- KLHL1 | c.1482C>A p.G494= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as COSV64787252; called by muse, mutect2, varscan2
- KNTC1 | c.3249A>G p.A1083= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV61085471; called by muse, mutect2, varscan2
- LDB3 | c.441C>T p.S147= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV99554649; called by muse, mutect2
- LRRC8E | c.1254G>A p.R418= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV60719498; called by muse, mutect2, varscan2
- LRRK1 | c.2541C>T p.Y847= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs764808328, COSV52628881; called by muse, mutect2, varscan2
- MUC5B | c.10902G>T p.V3634= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV101499989; called by muse, mutect2, varscan2
- NPAS4 | c.267A>C p.T89= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV60653282; called by muse, varscan2
- OR10Z1 | c.606C>T p.L202= | Silent (SNP) | VAF 39/113 reads (35%) | catalogued as COSV63526870; called by muse, mutect2, varscan2
- PHF19 | c.951G>A p.L317= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs1247762562, COSV65879211; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1134C>A p.G378= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV65047228, COSV65049994; called by muse, mutect2, varscan2
- RPL3L | c.1203G>A p.P401= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as rs140950130; called by muse, mutect2, varscan2
- RPTOR | c.1206G>A p.A402= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs747216581, COSV60820672; called by muse, mutect2, varscan2
- SKI | c.1059C>T p.S353= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as rs375991331; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC17A6 | c.445C>T p.L149= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV54142962; called by muse, mutect2, varscan2
- SLC25A24 | c.564A>G p.E188= | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as COSV99915867; called by muse, mutect2, varscan2
- TJP1 | c.978C>T p.S326= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs771873571, COSV62047522; called by muse, mutect2, varscan2
- TNFRSF8 | c.1206C>T p.S402= | Silent (SNP) | VAF 41/88 reads (47%) | catalogued as rs762096603, COSV55801848; called by muse, mutect2, varscan2
- UBA1 | c.1371G>T p.V457= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as COSV60116116; called by muse, mutect2, varscan2
- CFAP65 | c.542+88A>C | Intron (SNP) | VAF 4/21 reads (19%) | catalogued as COSV99838221; called by muse, mutect2, varscan2
